Somatic mutation profile of tumor specimen C3L-02163-01 (aliquot CPT0175120006) from CPTAC case C3L-02163, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.5 years (21,020 days).
Specimen C3L-02163-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b50873b7-186b-4bcf-b836-db35c2f3201a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02163-31 (Blood Derived Normal), aliquot CPT0175220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/020fd17f-ad27-444d-8cd1-a02b60e1379a

The open-access MAF lists 292 somatic variants for this specimen: 195 protein-altering or splice-affecting, 61 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 61, Intron 12, RNA 11, Nonsense Mutation 11, 3'UTR 6, Splice Site 5, 5'UTR 4, Splice Region 3, Frame Shift Ins 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.6447_6448dup p.K2150Ifs*19 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | catalogued as rs397507858; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 344/447 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD17A | c.635C>A p.S212* (on ENST00000292577 / NM_001130111.2; = p.S263* on NM_031213.4) | Nonsense Mutation (SNP) | VAF 151/562 reads (27%) | catalogued as COSV104377465; called by mutect2, varscan2
- AJUBA | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1260814442; called by muse, mutect2, varscan2
- AK7 | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 71/467 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs746706465, COSV99967045; called by muse, mutect2, varscan2
- ALPI | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs760471759; called by muse, mutect2, varscan2
- ANKMY1 | c.1633G>T p.V545L | Missense Mutation (SNP) | VAF 72/98 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs768606351, COSV99802908; called by muse, mutect2, varscan2
- BTN3A3 | c.776C>A p.S259* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as COSV55072677; called by muse, mutect2, varscan2
- CBFA2T2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs750056034; called by muse, mutect2, varscan2
- CCDC8 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 57/478 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV56772396; called by muse, mutect2, varscan2
- CDCA7L | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs757664469, COSV60944190; called by muse, mutect2, varscan2
- CFAP61 | c.1777C>G p.P593A | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99842597; called by muse, mutect2
- CIITA | c.2491G>A p.G831S | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs759652613; called by muse, mutect2, varscan2
- CNTNAP2 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.042); catalogued as rs1064795189; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE7 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs945662312, COSV99254688, COSV99255239; called by muse, mutect2, varscan2
- CRACD | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 160/308 reads (52%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV51730367; called by muse, mutect2, varscan2
- CTNND2 | c.3502G>A p.D1168N | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs756966820, COSV58908222; called by muse, mutect2, varscan2
- DAND5 | c.130G>C p.G44R | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.656); catalogued as rs1568238170; called by muse, mutect2, varscan2
- DPYSL3 | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs755360448, COSV58328481; called by muse, mutect2
- DSEL | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372577857; called by muse, mutect2, varscan2
- ECT2 | c.959A>G p.D320G (on ENST00000392692 / NM_001349098.2; = p.D289G on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/232 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99221451; called by muse, mutect2
- EPHA7 | c.1814C>T p.T605I | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.759); catalogued as rs777258745; called by muse, mutect2
- ESRRG | c.675G>T p.Q225H | Missense Mutation (SNP) | VAF 67/282 reads (24%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.496); catalogued as COSV63161350; called by muse, mutect2, varscan2
- FAM135B | c.353C>A p.T118K | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50523016; called by muse, mutect2, varscan2
- FAM171A1 | c.2456G>A p.G819E | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV65315644; called by muse, mutect2, varscan2
- FAM178B | c.1858G>A p.E620K (on ENST00000490605 / NM_001122646.3; = p.E60K on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.807); catalogued as rs753570962; called by muse, mutect2, varscan2
- FCGBP | c.6820G>T p.G2274C | Missense Mutation (SNP) | VAF 185/1850 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315956102; called by muse, mutect2
- FDXR | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as rs558115348; called by muse, mutect2, varscan2
- FGF14 | c.416T>A p.F139Y | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as COSV101084815; called by muse, mutect2, varscan2
- FOXA3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 86/398 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444890389, COSV56215273; called by muse, mutect2, varscan2
- FRMD5 | c.1632C>A p.F544L | Missense Mutation (SNP) | VAF 109/161 reads (68%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV68723549; called by muse, mutect2, varscan2
- GABRA6 | c.248dup p.R84Pfs*6 | Frame Shift Ins (INS) | VAF 37/166 reads (22%) | catalogued as rs755508078; called by mutect2, varscan2
- GCNT3 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 71/101 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV101251803; called by muse, mutect2, varscan2
- GRM8 | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as COSV58836610; called by muse, mutect2, varscan2
- HNRNPM | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs1349843676; called by muse, mutect2, varscan2
- IL31RA | c.1272G>A p.W424* | Nonsense Mutation (SNP) | VAF 113/193 reads (59%) | catalogued as rs771568255; called by muse, mutect2, varscan2
- ILDR2 | c.359G>T p.R120I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54830918; called by muse, mutect2, varscan2
- IPO4 | c.2570G>C p.G857A | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100269338; called by muse, mutect2, varscan2
- ITPR2 | c.4642G>A p.G1548R | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as rs541260584; called by muse, mutect2, varscan2
- KCNT2 | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99653678; called by muse, mutect2, varscan2
- KIF13A | c.3540G>C p.L1180F | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52457473, COSV99436776; called by muse, mutect2, varscan2
- KLF1 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 71/283 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs1293678069; called by muse, mutect2, varscan2
- KMT2C | c.205A>G p.M69V | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs530632312; called by muse, mutect2, varscan2
- KMT2D | c.15589G>A p.A5197T | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs1555185696; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRTAP6-1 | c.112T>A p.C38S | Missense Mutation (SNP) | VAF 141/462 reads (31%) | PolyPhen benign (0.075); catalogued as rs1202830324, COSV58168536; called by muse, mutect2, varscan2
- KRTAP9-1 | c.355T>G p.C119G | Missense Mutation (SNP) | VAF 75/617 reads (12%) | SIFT deleterious (0); catalogued as COSV59167065; called by muse, mutect2, varscan2
- KSR2 | c.1844C>T p.T615M | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as rs534046978, COSV56676747; called by muse, mutect2, varscan2
- LHX8 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775327141, COSV53955712, COSV53957679; called by muse, mutect2, varscan2
- LINGO2 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV58061284; called by muse, mutect2, varscan2
- LRP1B | c.7869G>T p.K2623N | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV67239753; called by muse, mutect2, varscan2
- LRRC7 | c.3566G>T p.G1189V (on ENST00000651989 / NM_001370785.2; = p.G1156V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99225280; called by muse, mutect2, varscan2
- MAGI2 | c.1244G>C p.R415P | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62670057; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MGLL | c.188G>A p.R63Q (on ENST00000398104 / NM_001003794.2; = p.R73Q on NM_007283.6) | Missense Mutation (SNP) | VAF 131/677 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374522575; called by muse, mutect2, varscan2
- MUC12 | c.2369C>A p.P790H (on ENST00000379442; = p.P647H on NM_001164462.1) | Missense Mutation (SNP) | VAF 101/668 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs1448579722; called by muse, mutect2, varscan2
- NCAPD3 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV99844762; called by muse, mutect2, varscan2
- NOTCH1 | c.4636G>T p.D1546Y | Missense Mutation (SNP) | VAF 256/640 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53106573; called by muse, mutect2, varscan2
- NUDT14 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100078609; called by muse, mutect2, varscan2
- OR10G8 | c.578C>G p.A193G | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV70909061; called by muse, mutect2, varscan2
- OR2T3 | c.691C>A p.H231N | Missense Mutation (SNP) | VAF 106/203 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.117); catalogued as COSV100613286; called by muse, mutect2, varscan2
- OR5A1 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as COSV57376553; called by muse, mutect2, varscan2
- OR5B21 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 105/265 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as rs1324366451, COSV100835125; called by muse, mutect2, varscan2
- PLCE1 | c.4048A>G p.I1350V | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1232980375; called by muse, mutect2, varscan2
- PODXL2 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 69/386 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs527636105; called by muse, mutect2, varscan2
- PPP1R3A | c.3182C>A p.A1061D | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV52878293; called by muse, mutect2, varscan2
- PSME4 | c.2782C>A p.R928= | Splice Region (SNP) | VAF 53/115 reads (46%) | catalogued as COSV101122523; called by muse, mutect2, varscan2
- REG3A | c.379G>T p.V127L | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV59410478; called by muse, mutect2, varscan2
- REG3A | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774925348; called by muse, varscan2
- RHBDF2 | c.1860C>G p.H620Q | Missense Mutation (SNP) | VAF 120/288 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99166278; called by muse, mutect2, varscan2
- RNASEH2A | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 123/269 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1285686950; called by muse, mutect2, varscan2
- SBK2 | c.687C>A p.C229* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100705055; called by muse, mutect2, varscan2
- SLC38A8 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 95/176 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0.384); catalogued as rs147289037; called by muse, mutect2, varscan2
- SLC4A10 | c.3209C>A p.P1070Q (on ENST00000446997 / NM_001354461.2; = p.P1040Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs773098267, COSV55796711; called by muse, mutect2, varscan2
- SOD1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs1217353001; called by muse, mutect2, varscan2
- SPATA31D1 | c.2288T>C p.M763T | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as COSV61202099; called by muse, mutect2
- TPRN | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated, low confidence (0.08); catalogued as rs1015524990; called by muse, mutect2, varscan2
- TRAFD1 | c.203A>T p.K68M | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as rs756327435; called by muse, mutect2, varscan2
- TRDN | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as rs1395279008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRHDE | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53860312; called by muse, mutect2, varscan2
- TRIM49 | c.140del p.P47Hfs*16 | Frame Shift Del (DEL) | VAF 138/444 reads (31%) | catalogued as COSV100315852; called by mutect2, pindel, varscan2
- UGT2B15 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100592431; called by muse, mutect2, varscan2
- AACS | c.184T>C p.W62R | Missense Mutation (SNP) | VAF 146/247 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL2 | c.1262C>A p.T421K | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ADTRP | c.90C>A p.D30E | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AHNAK | c.6570C>A p.N2190K | Missense Mutation (SNP) | VAF 212/325 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANO6 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ANXA7 | c.947C>G p.S316* (on ENST00000372919 / NM_001320880.2; = p.S294* on NM_001156.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- ARID5A | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPG | c.646A>G p.R216G | Missense Mutation (SNP) | VAF 110/205 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ATP9B | c.1596A>T p.K532N | Missense Mutation (SNP) | VAF 190/369 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ATRNL1 | c.1640G>T p.S547I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- BCHE | c.1567A>T p.S523C | Missense Mutation (SNP) | VAF 82/329 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- BCLAF1 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- BTBD8 | c.3629A>G p.N1210S (on ENST00000636805 / NM_001376131.1; = p.N697S on NM_015237.4) | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- BTC | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- CACNA1C | c.3639G>T p.W1213C | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CARMIL1 | c.727A>T p.S243C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CASP1 | c.1003C>G p.P335A (on ENST00000436863 / NM_033292.4; = p.P314A on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CCDC8 | c.1615T>A p.*539Rext*4 | Nonstop Mutation (SNP) | VAF 37/199 reads (19%) | called by muse, mutect2, varscan2
- CNGB1 | c.1873C>T p.H625Y | Missense Mutation (SNP) | VAF 137/204 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- CNTNAP5 | c.3886A>T p.T1296S | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- COL6A5 | c.4412T>C p.L1471P | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CPS1 | c.3141+2T>A p.X1047_splice | Splice Site (SNP) | VAF 36/90 reads (40%) | called by muse, mutect2, varscan2
- CRACDL | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 124/156 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD2 | c.5353T>A p.W1785R | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNA2 | c.2363A>C p.Q788P | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUBN | c.1248T>G p.Y416* | Nonsense Mutation (SNP) | VAF 45/169 reads (27%) | called by muse, mutect2, varscan2
- DACT2 | c.1319C>A p.A440D | Missense Mutation (SNP) | VAF 85/311 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DDX5 | c.1606A>C p.S536R | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DHX34 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK2 | c.4380+2T>G p.X1460_splice | Splice Site (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- DTX3L | c.1866C>A p.D622E | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPRS1 | c.3751A>G p.M1251V | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- EPX | c.505C>A p.R169S | Missense Mutation (SNP) | VAF 118/524 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EVPL | c.2331C>G p.S777R | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EXOC8 | c.1155G>T p.E385D | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- EYS | c.1230C>A p.D410E | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- FAM135B | c.1437T>A p.C479* | Nonsense Mutation (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- FAT3 | c.3480C>G p.N1160K | Missense Mutation (SNP) | VAF 82/226 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.7118T>C p.I2373T | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FBXO10 | c.659C>G p.T220S | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FSIP2 | c.18421C>T p.H6141Y | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- G6PD | c.267+8G>A | Splice Region (SNP) | VAF 184/219 reads (84%) | called by muse, mutect2, varscan2
- GALK2 | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 223/302 reads (74%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GC | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GGT7 | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GOLGA3 | c.1901A>T p.E634V | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HIVEP3 | c.5860A>G p.T1954A | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMX3 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 113/321 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IARS1 | c.683G>A p.W228* | Nonsense Mutation (SNP) | VAF 46/200 reads (23%) | called by muse, mutect2, varscan2
- ICAM1 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 93/485 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- INSR | c.3379G>C p.G1127R | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- IQCK | c.124T>A p.S42T | Missense Mutation (SNP) | VAF 80/395 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ITGA8 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNK5 | c.153C>G p.C51W | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- KDM6A | c.2702+1G>A p.X901_splice | Splice Site (SNP) | VAF 83/112 reads (74%) | called by muse, mutect2, varscan2
- KIF1A | c.2394C>A p.H798Q | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- KLHL13 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- KRT1 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 204/358 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- LCP1 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- LMX1B | c.487C>A p.L163M | Missense Mutation (SNP) | VAF 196/541 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAN1A2 | c.378A>C p.L126F | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- MAP3K19 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 131/181 reads (72%) | SIFT tolerated (0.64); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAST4 | c.5642G>T p.R1881L (on ENST00000403625 / NM_001164664.2; = p.R1692L on NM_015183.3) | Missense Mutation (SNP) | VAF 77/111 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- MCHR2 | c.906C>A p.N302K | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED13 | c.3711A>T p.E1237D | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MTBP | c.1826A>T p.Y609F | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC5B | c.15910A>G p.N5304D | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO18A | c.3002G>T p.R1001L | Missense Mutation (SNP) | VAF 175/430 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDNF | c.295A>T p.R99W | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- NFKBIE | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBP2A | c.272G>T p.S91I | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- OR11H2 | c.557G>C p.G186A (on ENST00000556246; = p.G197A on NM_001197287.1) | Missense Mutation (SNP) | VAF 93/479 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- OR2M5 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR5D13 | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- P4HA2 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 118/164 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH15 | c.2222C>A p.A741E | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCID2 | c.1113A>T p.G371= | Splice Region (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- PIK3C2G | c.2785G>C p.D929H (on ENST00000676171; = p.D888H on NM_004570.5) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PKHD1 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- POLK | c.2528+1G>C p.X843_splice | Splice Site (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- RNF123 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1L1 | c.5266A>G p.K1756E | Missense Mutation (SNP) | VAF 165/345 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPP38 | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 53/163 reads (33%) | called by muse, mutect2, varscan2
- SLC35A1 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.086); called by muse, mutect2
- SLC3A2 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 79/126 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC6A4 | c.1214T>C p.L405P | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPACA1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, varscan2
- SPAST | c.1341G>T p.L447F | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTAN1 | c.2220G>T p.Q740H | Missense Mutation (SNP) | VAF 153/447 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.904C>G p.R302G | Missense Mutation (SNP) | VAF 51/204 reads (25%) | PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TACC1 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TARS3 | c.2072+1G>A p.X691_splice | Splice Site (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- TBXAS1 | c.905A>T p.D302V | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- TCN1 | c.769T>A p.Y257N | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TGIF2LX | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 473/566 reads (84%) | SIFT tolerated (0.14); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TMEM178B | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TMPRSS15 | c.1693C>A p.Q565K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- TNFAIP6 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNRC18 | c.7516C>G p.P2506A | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOPAZ1 | c.2936G>T p.G979V | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- UBR3 | c.3341A>G p.D1114G | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- UNC80 | c.113T>A p.L38Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USH2A | c.11729A>T p.E3910V | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- USP42 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H18 | c.2264A>C p.E755A | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZDHHC15 | c.373A>C p.S125R | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- ZMAT1 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- ZNF268 | c.1057A>C p.I353L | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF423 | c.395A>G p.D132G (on ENST00000563137 / NM_001379286.1; = p.D124G on NM_015069.4) | Missense Mutation (SNP) | VAF 102/152 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF432 | c.1918C>A p.L640I | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF728 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 155/316 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZNF831 | c.3368A>T p.D1123V | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF853 | c.1331A>C p.Q444P | Missense Mutation (SNP) | VAF 155/247 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ZSCAN30 | c.1084T>A p.C362S | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AIFM2 | c.975A>T p.A325= | Silent (SNP) | VAF 44/162 reads (27%) | called by muse, mutect2, varscan2
- ATP2A3 | c.1059G>A p.T353= | Silent (SNP) | VAF 81/535 reads (15%) | catalogued as rs779341611; called by muse, mutect2, varscan2
- BTN3A3 | c.1278A>T p.T426= | Silent (SNP) | VAF 74/231 reads (32%) | called by muse, mutect2, varscan2
- CARMIL1 | c.726G>A p.V242= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- CNN2 | c.258A>G p.E86= | Silent (SNP) | VAF 29/122 reads (24%) | called by muse, mutect2, varscan2
- DTD1 | c.546C>T p.S182= | Silent (SNP) | VAF 36/384 reads (9%) | called by muse, mutect2
- EPHA3 | c.2535C>A p.P845= | Silent (SNP) | VAF 36/58 reads (62%) | called by muse, varscan2
- ERO1A | c.132T>C p.D44= | Silent (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- FAM205A | c.3612C>A p.P1204= | Silent (SNP) | VAF 68/251 reads (27%) | called by muse, mutect2, varscan2
- GAK | c.1269A>T p.P423= | Silent (SNP) | VAF 52/145 reads (36%) | catalogued as COSV58506483; called by muse, mutect2, varscan2
- GRID2IP | c.75C>T p.G25= | Silent (SNP) | VAF 189/918 reads (21%) | called by muse, mutect2, varscan2
- HECW1 | c.2865C>A p.V955= | Silent (SNP) | VAF 79/160 reads (49%) | called by muse, mutect2, varscan2
- HSPA6 | c.1179C>T p.L393= | Silent (SNP) | VAF 30/144 reads (21%) | called by muse, mutect2, varscan2
- ICAM5 | c.2571C>T p.A857= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs1402647882, COSV55749310; called by muse, mutect2, varscan2
- IGKV1-17 | c.33G>C p.G11= | Silent (SNP) | VAF 153/524 reads (29%) | called by muse, varscan2
- IRAK3 | c.825C>T p.S275= | Silent (SNP) | VAF 71/445 reads (16%) | called by muse, mutect2, varscan2
- LRP1B | c.2223T>A p.P741= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV101257788; called by muse, mutect2, varscan2
- LRP6 | c.651G>A p.Q217= | Silent (SNP) | VAF 83/209 reads (40%) | called by muse, mutect2, varscan2
- MAG | c.1374G>C p.R458= | Silent (SNP) | VAF 102/452 reads (23%) | called by muse, mutect2, varscan2
- MED28 | c.15A>T p.L5= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs1270351193; called by muse, mutect2, varscan2
- MEGF8 | c.6408C>T p.C2136= (on ENST00000251268 / NM_001271938.2; = p.C2069= on NM_001410.3) | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs751851442, COSV52074122, COSV52075594; called by muse, mutect2, varscan2
- MFSD3 | c.162G>T p.L54= | Silent (SNP) | VAF 74/358 reads (21%) | called by muse, mutect2, varscan2
- MFSD3 | c.339C>G p.A113= | Silent (SNP) | VAF 193/407 reads (47%) | called by muse, mutect2, varscan2
- MIA3 | c.1842A>G p.Q614= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as rs768745273; called by mutect2, varscan2
- MUC4 | c.10380C>T p.T3460= | Silent (SNP) | VAF 327/2179 reads (15%) | catalogued as rs745694333; called by muse, varscan2
- NAV3 | c.2058T>G p.V686= | Silent (SNP) | VAF 30/186 reads (16%) | called by muse, mutect2, varscan2
- NKX2-4 | c.90C>A p.A30= | Silent (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- NOL4 | c.690G>C p.R230= | Silent (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- NOM1 | c.2520G>C p.V840= | Silent (SNP) | VAF 45/232 reads (19%) | called by muse, mutect2, varscan2
- NR5A2 | c.1476G>A p.Q492= (on ENST00000367362 / NM_205860.3; = p.Q446= on NM_003822.5) | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as rs1465628274; called by muse, mutect2, varscan2
- OLFM4 | c.9C>T p.P3= | Silent (SNP) | VAF 62/93 reads (67%) | catalogued as rs138499950, COSV99524637; called by muse, mutect2, varscan2
- OR1N2 | c.498G>A p.L166= | Silent (SNP) | VAF 70/167 reads (42%) | called by muse, mutect2, varscan2
- OR2L13 | c.225C>T p.T75= | Silent (SNP) | VAF 41/213 reads (19%) | catalogued as COSV63554298; called by muse, mutect2, varscan2
- OR2M3 | c.801C>A p.S267= | Silent (SNP) | VAF 88/390 reads (23%) | catalogued as COSV71759374; called by muse, mutect2, varscan2
- OR51A7 | c.192C>G p.A64= | Silent (SNP) | VAF 58/86 reads (67%) | called by muse, mutect2, varscan2
- PCDH11X | c.3180C>G p.G1060= | Silent (SNP) | VAF 190/365 reads (52%) | called by muse, mutect2, varscan2
- PEG3 | c.552G>A p.R184= | Silent (SNP) | VAF 79/331 reads (24%) | catalogued as COSV55637255, COSV99689913; called by muse, mutect2, varscan2
- PFKFB1 | c.948G>A p.L316= | Silent (SNP) | VAF 54/136 reads (40%) | called by muse, mutect2, varscan2
- PHF23 | c.547C>A p.R183= | Silent (SNP) | VAF 55/238 reads (23%) | catalogued as rs1198695014, COSV99138345; called by muse, mutect2, varscan2
- POTEH | c.171C>G p.L57= | Silent (SNP) | VAF 158/384 reads (41%) | catalogued as rs1281814075, COSV58882331; called by muse, varscan2
- PTH2R | c.164G>A p.*55= | Silent (SNP) | VAF 28/99 reads (28%) | called by muse, mutect2, varscan2
- PXDN | c.2529C>T p.D843= | Silent (SNP) | VAF 61/240 reads (25%) | catalogued as rs949156715; called by muse, mutect2, varscan2
- RADIL | c.2469C>A p.G823= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as COSV101271660; called by muse, mutect2
- RASGRP2 | c.748C>T p.L250= | Silent (SNP) | VAF 253/388 reads (65%) | called by muse, mutect2, varscan2
- RGL3 | c.1524C>A p.S508= | Silent (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- SBNO1 | c.1530A>G p.V510= (on ENST00000420886; = p.V509= on NM_018183.5) | Silent (SNP) | VAF 136/205 reads (66%) | called by muse, mutect2, varscan2
- SF3B4 | c.1011A>G p.P337= | Silent (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- SHANK1 | c.3423G>C p.P1141= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs568941289, COSV99521986; called by muse, mutect2, varscan2
- STRC | c.4017G>A p.Q1339= | Silent (SNP) | VAF 133/407 reads (33%) | called by muse, mutect2, varscan2
- TANC2 | c.5139G>A p.Q1713= | Silent (SNP) | VAF 76/299 reads (25%) | called by muse, mutect2, varscan2
- TBCD | c.2616C>A p.R872= | Silent (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- THOC2 | c.2451G>A p.L817= | Silent (SNP) | VAF 158/186 reads (85%) | called by muse, mutect2, varscan2
- TLR1 | c.385C>T p.L129= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- TNFRSF21 | c.1362C>G p.A454= | Silent (SNP) | VAF 125/378 reads (33%) | called by muse, mutect2, varscan2
- TNPO2 | c.1548C>G p.L516= | Silent (SNP) | VAF 48/258 reads (19%) | called by muse, mutect2, varscan2
- TRBV20-1 | c.117C>T p.S39= | Silent (SNP) | VAF 40/184 reads (22%) | called by muse, mutect2, varscan2
- TTC28 | c.1278G>A p.E426= | Silent (SNP) | VAF 68/281 reads (24%) | called by muse, mutect2, varscan2
- UBTFL1 | c.780C>T p.R260= | Silent (SNP) | VAF 40/348 reads (11%) | called by muse, mutect2, varscan2
- ZBED8 | c.66A>T p.V22= | Silent (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- ZBTB41 | c.1815C>T p.C605= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as rs140531073; called by muse, mutect2, varscan2
- ZNF883 | c.154C>A p.R52= | Silent (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- ABCC10 | c.-11-81G>T | Intron (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- AC083899.1 | n.3193C>T | RNA (SNP) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- AC116655.1 | n.67A>T | RNA (SNP) | VAF 46/202 reads (23%) | called by muse, mutect2, varscan2
- AC116655.1 | n.66C>A | RNA (SNP) | VAF 47/203 reads (23%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.941C>T | RNA (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- BTNL10 | n.258G>T | RNA (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- C3 | c.4172+38C>T | Intron (SNP) | VAF 60/321 reads (19%) | catalogued as rs1173792403; called by muse, mutect2, varscan2
- C3orf33 | c.115-1559A>T | Intron (SNP) | VAF 103/158 reads (65%) | called by muse, mutect2, varscan2
- C5orf17 | n.413C>G | RNA (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- CD8B | c.*29A>G | 3'UTR (SNP) | VAF 10/34 reads (29%) | catalogued as rs751200056; called by mutect2, varscan2
- CRB1 | c.1172-7106C>A | Intron (SNP) | VAF 30/51 reads (59%) | called by muse, mutect2, varscan2
- DPP6 | c.627+20842C>A | Intron (SNP) | VAF 43/273 reads (16%) | called by muse, mutect2, varscan2
- DPP6 | c.627+20843A>G | Intron (SNP) | VAF 43/277 reads (16%) | catalogued as rs1215693655; called by muse, mutect2, varscan2
- DTNA | c.1094+1805C>T | Intron (SNP) | VAF 12/44 reads (27%) | catalogued as rs1024046661; called by mutect2, varscan2
- EYS | c.1767-6807C>T | Intron (SNP) | VAF 193/459 reads (42%) | called by muse, mutect2, varscan2
- FAM90A27P | n.1035G>T | RNA (SNP) | VAF 22/455 reads (5%) | called by muse, mutect2
- LVRN | c.*5T>C | 3'UTR (SNP) | VAF 96/145 reads (66%) | called by muse, mutect2, varscan2
- MCOLN1 | c.-107G>T | 5'UTR (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- MIR520F | n.6G>T | RNA (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- MOCS1 | c.*544T>G | 3'UTR (SNP) | VAF 52/159 reads (33%) | called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516034 A>T | 5'Flank (SNP) | VAF 81/388 reads (21%) | called by muse, mutect2, varscan2
- OR2W5 | n.967C>A | RNA (SNP) | VAF 154/309 reads (50%) | catalogued as rs374342591; called by muse, mutect2, varscan2
- PIPSL | n.1443G>A | RNA (SNP) | VAF 77/252 reads (31%) | called by muse, mutect2, varscan2
- RANBP17 | c.2231+19G>A | Intron (SNP) | VAF 229/349 reads (66%) | called by muse, mutect2, varscan2
- REXO1L1P | chr8:85655132 T>C | 3'Flank (SNP) | VAF 162/2163 reads (7%) | catalogued as rs780708472; called by muse, varscan2
- RNF32 | chr7:156640601 C>T | 5'Flank (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- SATL1 | c.-130C>G | 5'UTR (SNP) | VAF 170/206 reads (83%) | catalogued as COSV60578337; called by muse, mutect2, varscan2
- SCN1A | c.3430-24T>A | Intron (SNP) | VAF 59/296 reads (20%) | called by muse, mutect2, varscan2
- SLC20A1 | c.*139G>A | 3'UTR (SNP) | VAF 79/116 reads (68%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2668C>A | RNA (SNP) | VAF 63/271 reads (23%) | called by muse, mutect2, varscan2
- VAMP8 | c.-40G>T | 5'UTR (SNP) | VAF 49/241 reads (20%) | called by muse, mutect2, varscan2
- VPS11 | c.-450G>A | 5'UTR (SNP) | VAF 31/151 reads (21%) | called by muse, mutect2, varscan2
- WIPI1 | c.1293+1529G>C | Intron (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2
- XIRP2 | c.*994A>C | 3'UTR (SNP) | VAF 24/106 reads (23%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+5467C>T | Intron (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- ZNF777 | c.*59C>T | 3'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, varscan2
